Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GR, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GR-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, renal cell.
Chromophobe type 8317/3
Site: R Kidney NOS
C64.9
9/24/13

Surgical Pathology Report

Diagnosis:

A: Right kidney, nephrectomy

- Renal cell carcinoma, chromophobe type, nuclear grade 2 (of 4), tumor size 6.0 cm in greatest dimension, tumor confined to kidney, surgical margins free of tumor
- Tiny renomedullary interstitial cell tumor, 2 mm, in medullary pyramid
- Portions of renal artery, vein and ureter with no tumor seen

B: Hilar lymph node, removal

- No tumor seen in one lymph node (0/1)

Clinical History:

The patient is a year-old with a right renal mass.

Gross Description:

Received are two appropriately labeled containers.

Container A:

Specimen fixation: formalin

Type of specimen: laparoscopic nephrectomy

Side of specimen: right

Size and weight of specimen: 450 grams, 15.5 x 9.0 x 7.0 cm

Presence/absence of adrenal gland: absent

Tumor description/site: circumscribed, tan/orange with focal hemorrhage and present in the lower pole

Tumor size: 6.0 x 5.0 x 4.5 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined to the lower pole but expanding the capsule

Extent of invasion:

Perirenal adipose tissue: tumor grossly does not involve

Gerota's fascia: tumor grossly does not involve

Renal vein: tumor grossly does not involve

Ureter: tumor grossly does not involve

Other organs: tumor grossly does not involve

Surgical margins:

Perirenal adipose tissue: negative, less than 0.1 cm from the anterior surface

[page 2 of 3]
Renal vein: negative
Renal artery: negative
Ureter: negative

Description of kidney away from tumor: grossly unremarkable; no cysts or nodules present
Lymph nodes (hilar): none identified
Other significant findings: none
Tissue submitted for special investigations: none

Block summary:

A1 - ureter, vascular, tangential margins of resection
A2,A3 - tumor expanding renal capsule
A4 - tumor and overlying pelvic urothelium
A5 - tumor and adjacent renal parenchyma
A6 - tumor and anterior margin closest approach
A7 - sample from hilar fat
A8 - representative of upper pole, normal appearing kidney
A9 - 0.5 cm solid white nodule located in the central renal parenchyma

Container B is additionally labeled "hilar lymph node." It consists of a 2.9 x 2.4 x 0.6 cm aggregate of fibrofatty tissue containing a solitary 1.7 x 1.2 x 0.6 cm lymph node candidate. The lymph node is sectioned and entirely submitted in block B1. The remainder of the fat is submitted as block B2.

Light Microscopy:
Light microscopic examination is performed by Dr.

Histologic tumor type/subtype: renal cell carcinoma, chromophobe type

Histologic grade (if applicable): grade 2 (of 4)

Tumor size (greatest dimension): 6.0 cm

Extent of tumor invasion:
Capsular invasion/perirenal adipose tissue: absent
Gerota's fascia: absent
Renal vein: absent
Ureter: absent
Venous (large vessel): absent
Lymphatic (small vessel): absent

Histologic assessment of surgical margins:
Perirenal adipose tissue: free of tumor
Gerota's fascia: free of tumor

[page 3 of 3]
Renal vein: free of tumor
Renal artery: free of tumor
Ureter: free of tumor

Adrenal gland: absent

Lymph nodes: no tumor seen in one lymph node (0/1)

Other significant findings: a tiny renomedullary interstitial cell tumor, 2 mm (*Notation added
This is a non-malignant tumor, M8966/0*).

Diagnosis Discrepancy	lw 8/31/13		✓
Prior Malignancy History	Prior TX	✓	

Source: NCI Genomic Data Commons file 388f7642-06cc-4903-9b22-186623399513 (TCGA-UW-A7GR.E0AA1F55-51DD-4D22-81E5-E3473A195B64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).